Gene-level copy-number profile of tumor specimen TCGA-IN-8462-01A from TCGA case TCGA-IN-8462, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 80.1 years (29,242 days).
Specimen TCGA-IN-8462-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.d3ead62d-d6ec-406a-aaba-6eb1678de456.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-8462-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0633b47c-af2e-4b05-882c-8397803e191f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 116; copy number 1: 16,022; copy number 2: 38,517; copy number 3: 3,217; copy number 4: 1,005; copy number 5: 271; copy number 6: 491; copy number 7: 15; copy number 8: 129; copy number 9: 8; copy number 10: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-8462-01A-11D-2338-01): tumor purity 0.55, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 109 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:22,495,570–22,869,362, 13 genes: HERC2P2, GOLGA8IP, RN7SL495P, WHAMMP3, AC138649.2, AC138649.5, AC138649.4, PDCD6IPP1, AC138649.3, AC138649.1, AC011767.1, NIPA1, NIPA2.
- chr15:24,955,034–25,420,336, 81 genes (within-gene range 0–2) (broad region; genes not listed).
- chr15:39,472,703–39,920,266, 10 genes (within-gene range 0–1): AC109630.1, AC022196.1, THBS1, AC037198.1, AC037198.2, FSIP1, AC023908.2, AC023908.3, GPR176, AC023908.1.
- chr15:46,827,526–46,827,958, 1 gene: AC073941.2.
- chr15:53,946,709–54,633,414, 4 genes (within-gene range 0–1): AC084759.2, UNC13C, AC010867.1, HNRNPA1P74.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 934 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:106,570,771–107,459,564, 15 genes, copy number 7 (within-gene range 2–7): RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr7:70,972–5,872,050, 131 genes, copy number 5–8 (broad region; genes not listed).
- chr9:128,191,655–130,501,274, 93 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr14:26,443,090–26,806,467, 3 genes, copy number 9: NOVA1, AL079343.1, LINC02588.
- chr14:26,775,495–26,918,594, 5 genes, copy number 9: LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307.
- chr14:29,576,479–38,041,442, 153 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr14:49,693,105–53,883,740, 104 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr14:53,917,270–56,650,606, 51 genes, copy number 6 (within-gene range 2–6): AL138479.1, MIR5580, BMP4, AL138479.2, ATP5F1CP1, CDKN3, CNIH1, AL359792.1, GMFB, CGRRF1, SAMD4A, AL133444.1, GCH1, RNU6ATAC9P, MIR4308, FDPSP3, WDHD1, RPSAP13, SOCS4, MAPK1IP1L, LGALS3, DLGAP5, AL139316.1, AL158801.4, COX5AP1, AL158801.2, FBXO34, AL158801.1, Metazoa_SRP, CHMP4BP1, AL158801.3, ATG14, HMGN1P1, TBPL2, RPL21P6, KTN1-AS1, RPL7AP4, ABI1P1, KTN1, Y_RNA, AL355773.1, RPL13AP3, LINC00520, AL163952.1, AL138995.1, PELI2, AL355073.1, AL355073.2, LINC02284, TMEM260, AL355103.1.
- chr17:66,302,613–69,903,000, 86 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:21,182,503–42,691,422, 293 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,608. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
